CCDI case PBCFBJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/2e11ba57-c14a-4b81-bdd6-82c8496cecf7

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Tumor cells, benign: ICD-O-3 morphology code: 8001/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 17.8 years (6,495 days).

Biospecimens (3 samples)
- Samples 0DR6XZ, 0DS4MH (2 with the same recorded description): Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR6Y9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
